Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A3QI, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A3QI-01A (Primary Tumor).

[page 1 of 4]
Res

SURGICAL PATHOLOGY (Order [REDACTED])

Patient

Patient Name

Sex

DOB

Results

Specimen #: [REDACTED]
Submitting Physician: [REDACTED]

FINAL DIAGNOSIS

1. Distal right ureter, biopsy (A) - Negative for neoplasm.
2. Distal left ureter, biopsy (B) - Negative for neoplasm.
3. Right pelvic lymph node, excision (C) - One lymph node, negative for neoplasm (0/1).
4. Left pelvic lymph node, excision (D) - Fourteen lymph nodes, negative for neoplasm (0/14)
5. Right pelvic lymph node #2, excision (E) - Thirteen lymph nodes, negative for neoplasm (0/13).
6. Urinary bladder, radical cystoprostatectomy (F) - Invasive high grade papillary urothelial carcinoma (4.5 cm).
- The tumor invades through muscularis propria (detrusor muscle) and into perivesical fat.
- The bilateral ureteral, urethral, peripheral and all remaining resection margins are negative for tumor.
- Lymphovascular invasion is present.
- See comment.
7. Prostate, radical cystoprostatectomy (F) - High grade prostatic intraepithelial neoplasia.
- The prostatic urethra and parenchyma are not involved by urothelial carcinoma.
8. Distal prostatic urethra, resection (G) - Negative for neoplasm.

COMMENT

Specimen Type:
Radical cystoprostatectomy

Tumor Size, Greatest dimension: 4.5 cm

Histologic Type:
Urothelial carcinoma

Urothelial Carcinoma: (WHO)
High-grade

ICD-O-3 carcinoma, urothelial, NOS

8120/3

Site: bladder, posterior wall

2-29-12

C67.4

[page 2 of 4]
Adenocarcinoma and Squamous Carcinoma:
N/A

Associated Epithelial Lesions: (check all that apply)
None identified

Margins:
Margins uninvolved by invasive carcinoma

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):
Present

Direct Extension of Invasive Tumor:
Perivesical fat

Other Diagnoses:

Pathologic Stage:

Primary Tumor: (pT)
pT3b: Macroscopically invades perivesical fat (extravesical mass)

Regional Lymph Nodes: (pN)
pN0: No regional lymph node metastasis
Specify: Number examined 28: Number involved (any size): 0

Distant Metastasis (pM): pMX: Cannot be assessed

(Electronic Signature)

SPECIMEN SUBMITTED

A: DISTAL RIGHT URETER
B: DISTAL LEFT URETER
C: RIGHT PELVIC LYMPH NODE
D: LEFT PELVIC LYMPH NODES
E: RIGHT PELVIC LYMPH NODES #2
F: BLADDER AND PROSTATE
G: DISTAL PROSTATIC URETHRA

CLINICAL DATA

BLADDER CA
G: RULE OUT CA

INTRAOPERATIVE CONSULT DIAGNOSIS

A. Cross section of ureter. Negative for malignancy (Dr.
B. Cross section of ureter. Negative for malignancy (Dr.
C. Negative for neoplasm (Dr.
G. Negative for neoplasm (Dr.

GROSS DESCRIPTION

A. Received fresh at the frozen desk is a specimen labeled "distal right ureter". It consists of a single piece of lumen that measures 0.5 x 0.5 x

[page 3 of 4]
0.1 cm. The specimen is totally submitted for frozen section in cassette A1.

B. Received fresh at the frozen desk is a specimen labeled "distal left ureter". It consists of a single piece of soft tissue with lumen that measures 0.6 x 0.4 x 0.2 cm. The specimen is totally submitted for frozen section in cassette B1.

C. Received fresh at the frozen desk is a specimen labeled "right pelvic lymph node". It consists of a single piece of adipose and fibrous tissue without a distinct nodule. The specimen is totally submitted for frozen section in cassette C1.

D. Received fresh labeled "left pelvic lymph nodes" are multiple fragments of yellow fibrofatty tissue aggregating to 6.5 x 6.5 x 1.0 cm. Palpation reveals ten pink firm nodules ranging in size from 0.3 to 1.5 cm in greatest dimension. The specimen is entirely submitted as follows: D1 five nodules; D2 three nodules; D3 one nodule; D4 - D6 remaining fat.

E. Received fresh labeled "right pelvic lymph nodes #2" are multiple fragments of yellow fibrofatty tissue aggregating to 6.5 x 5.5 x 1.0 cm. Palpation reveals nine tan firm nodules ranging in size from 0.5 to 9.0 cm in greatest dimension. The largest nodule is predominantly fat replaced. The specimen is totally submitted as follows: E1 two nodules; E2 two nodules; E3 two nodules; E4 two nodules; E5 - E7 largest nodule sectioned and totally submitted; E8 - E10 remaining fat.

F. Received in formalin is a specimen consisting of a urinary bladder, bilateral ureters, prostate and attached seminal vesicles and vas deferentia. The bladder measures 2.0 x 5.5 x 4.5 cm. The external surface of the bladder is covered by smooth lining at the dome and fibroadipose tissue of the remaining portion. After the bladder is opened, a firm white papillary-like mass is identified measuring 4.5 x 4.0 x 2.0 cm within the posterior wall. The mass is papillary and solid. On sectioning, the mass extends through the muscularis propria into the perivesical adipose tissue retracting the overlying serosa. The serosal surface appears involved. The remaining bladder mucosa is unremarkable. The wall of the bladder appears thickened. A segment of right ureter measures 2.8 cm in length and is patent. Its mucosal surface is smooth and glistening. A segment of left ureter is 2.2 cm in length and its mucosa is also unremarkable. The prostate measures 4.5 cm transversely, 3.0 cm anteroposteriorly and 3.0 cm craniocaudally. The capsular surface is smooth. The gland is inked with blue on the right and yellow on the left and sectioned from apex to base transversely at 3 mm intervals perpendicular to the urethra. The urethra has been amputated in the same plane as the prostatic urethra, therefore, a shave margin cannot be obtained. Cross sections of the prostate reveal a tan solid cut surface without any definitive lesions. Rubbery nodularity is not present. The seminal vesicles are unremarkable. Segments of vas deferens are also unremarkable. Representative sections are submitted as follows: F1 right ureter; F2 left ureter; F3 posterior bladder wall with mass retracting local surface; F4 posteriori wall mass; F5 posterior wall mass in relation to perivesical fat; F6 anterior bladder wall; F7 right bladder wall; F8 left bladder wall; F9 dome of bladder; F10 trigone in relation to posterior wall mass; F11 apex right; F12 apex left; F13 3 mm right; F14 3 mm left; F15 6 mm right; F16 6 mm left; F17 9 mm right; F18 9 mm left; F19 12 mm right; F20 12 mm left; F21 15 mm anterior right; F22 15

[page 4 of 4]
mm anterior left; F23 15 mm posterior right; F24 15 mm posterior left; F25 18 mm anterior right; F26 18 mm anterior left; F27 18 mm posterior right; F28 18 mm posterior left; F29 seminal vesicle right; F30 seminal vesicle left.

G. Received fresh at the frozen desk is a specimen labeled "distal prostatic urethra" which consists of a single fragment of red-tan soft tissue measuring 2.5 x 1 x 0.9 cm and is entirely submitted for frozen in Gl.

Patient ID #: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Date of Report: [REDACTED]
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Submitted by: [REDACTED]
Location: [REDACTED]
Test performed by: [REDACTED]

Lab and Collection

SURGICAL PATHOLOGY (Order # [REDACTED]) on [REDACTED] - Lab and Collection Information

Result History

SURGICAL PATHOLOGY (Order # [REDACTED]) on [REDACTED] - Order Result History Report

Result Information

Result Date and Time	Status	Provider Status
[REDACTED]	Final result	Reviewed

MyChart Status:

This result is currently not released to

[Display Full Result Report](#)

[Display Order Report](#)

Source: NCI Genomic Data Commons file b1eca987-f00a-4b02-b50f-993274dbd5e2 (TCGA-GV-A3QI.3792A65B-C233-4DDF-88F8-8829B73616FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).